TCGA case TCGA-C5-A2LT — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fb66b7f5-22ca-4d4d-97c2-30e6edfff781

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 38 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 38.2 years (13,966 days); Year of diagnosis: 2001; Method of diagnosis: Biopsy; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 31; Lymphatic invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 115 days; Days to treatment end: 152 days; Number of cycles: 6; Prescribed dose: 50; Prescribed dose units: mg/m2/wk; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 115 days; Days to treatment end: 152 days; Treatment dose: 5,040 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.

Follow-up (3 entries)
- Day 14 (preoperative): ECOG performance status: 1.
- Day 110 (prior to adjuvant therapy): ECOG performance status: 1.
- Days to follow up: 2,226 days (6.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV70].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 163 cm; BMI: 22.2.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Current User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 19; Age at onset: 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A2LT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 180 mg.
  Slide TCGA-C5-A2LT-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-C5-A2LT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A2LT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 2; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 2; Tobacco smoking history indicator: 2; Tumor response: Complete response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Margins involved hysterectomy: Other Location, specify; Other involved margins: margins free of tumor; Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Absent; HPV types other: 70; Pcr primer pairs: GP5+/GP6+.
- Human papillomavirus types: HPV types positive: Other HPV type(s).
- Follow-up form: Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; Radiation adjuvant indicator: Yes; Radiation therapy xrt type: External beam radiation; Chemo concurrent dose: 50mg/m2; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 6; New tumor event diagnosis indicator: No.
- Follow-up form, Radiation supplemental: Radiation therapy dose paraaortic nodes: 0; Radiation therapy status: Completed as Planned.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,226 days; disease-specific survival: no event (censored), 2,226 days; disease-free interval: no event (censored), 2,226 days; progression-free interval: no event (censored), 2,226 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A2LT-01A-11D-A18H-01): tumor purity 0.44, ploidy 3.82, whole-genome doublings 1.
